Somatic mutation profile of tumor specimen C3L-05987-02 (aliquot CPT0360850009) from CPTAC case C3L-05987, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 80.0 years (29,202 days).
Specimen C3L-05987-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46dc279b-1443-48df-8212-4b3a7bb0a3a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05987-31 (Blood Derived Normal), aliquot CPT0360880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77f2bd65-c068-4eb5-bf00-12a20ee890b2

The open-access MAF lists 222 somatic variants for this specimen: 143 protein-altering or splice-affecting, 70 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 70, Intron 6, Nonsense Mutation 6, Splice Region 4, Frame Shift Del 2, Splice Site 2, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TBX5 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565941579; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976542769, COSV99835917; called by muse, mutect2, varscan2
- ANGPT1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 59/419 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV52440135; called by muse, mutect2, varscan2
- ASMT | c.941C>T p.P314L (on ENST00000381229; = p.P342L on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/540 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs1303502192; called by muse, mutect2, varscan2
- CDK11A | c.1876T>A p.F626I (on ENST00000378633 / NM_001313896.2; = p.F623I on NM_024011.4) | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52308737; called by muse, mutect2, varscan2
- CHD6 | c.7481G>A p.G2494E | Missense Mutation (SNP) | VAF 59/510 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749828766, COSV64691957; called by muse, mutect2, varscan2
- CLCN1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1204927357, CM1510283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 54/375 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as COSV62240163; called by muse, mutect2, varscan2
- CNTNAP5 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT tolerated (0.64); PolyPhen probably damaging (1); catalogued as COSV101444152; called by muse, mutect2, varscan2
- COL4A1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.12); catalogued as rs1333599538; called by muse, mutect2, varscan2
- COL4A4 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1479512818, COSV100306272; called by muse, mutect2, varscan2
- CORO7 | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 89/502 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs531731448, COSV99228325; called by muse, mutect2, varscan2
- CPZ | c.824G>A p.R275H (on ENST00000360986 / NM_001014447.3; = p.R264H on NM_003652.3) | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749063388, COSV59921949; called by muse, mutect2, varscan2
- CRISP1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV59993135; called by muse, mutect2, varscan2
- DMBT1 | c.6718C>T p.R2240W (on ENST00000338354 / NM_001377530.1; = p.R1483W on NM_004406.3) | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.924); catalogued as rs201079729; called by muse, mutect2, varscan2
- DNAH5 | c.12112G>A p.E4038K | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54203893, COSV99454417; called by muse, mutect2, varscan2
- DSG1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 22/185 reads (12%) | catalogued as rs145081747, CM086709; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1270644579; called by muse, mutect2, varscan2
- EGF | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as COSV99491407; called by muse, mutect2, varscan2
- ENTR1 | c.1255C>T p.L419F (on ENST00000357365 / NM_001039707.2; = p.L396F on NM_006643.4) | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53732461; called by muse, mutect2, varscan2
- FLNC | c.602-1G>A p.X201_splice | Splice Site (SNP) | VAF 68/360 reads (19%) | catalogued as rs1187796665; called by muse, mutect2, varscan2
- GCNT3 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs762250026; called by muse, mutect2, varscan2
- GRIN2A | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 90/453 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100409852, COSV58020198; called by muse, mutect2, varscan2
- GUCY2D | c.2394G>A p.M798I | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54697878; called by muse, mutect2, varscan2
- GYS2 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53921313; called by muse, mutect2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 116/1122 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by muse, mutect2
- IGSF9 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 77/446 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as rs752173288; called by muse, mutect2, varscan2
- IQCH | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 74/475 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs1489250093; called by muse, mutect2, varscan2
- IRX1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs949207066; called by muse, mutect2, varscan2
- KHDRBS2 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55490975; called by muse, mutect2, varscan2
- KLHL21 | c.71_88del p.G24_R29del | In Frame Del (DEL) | VAF 104/512 reads (20%) | catalogued as rs1557438115; called by mutect2, varscan2
- KRT28 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1199919717; called by muse, mutect2, varscan2
- LAMA3 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 94/441 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV100557019; called by muse, mutect2, varscan2
- LCT | c.3659G>A p.R1220K | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1288033852; called by muse, mutect2, varscan2
- LIN37 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50000546; called by muse, mutect2, varscan2
- LOXHD1 | c.6815C>T p.S2272F (on ENST00000642948; = p.S2210F on NM_144612.7) | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1420086937; called by muse, mutect2, varscan2
- LPAR5 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 92/518 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV61692680, COSV61692712, COSV61693137; called by muse, mutect2, varscan2
- MINDY4 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs759611015; called by muse, mutect2, varscan2
- MMGT1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs782380372, COSV60003228; called by muse, mutect2, varscan2
- MROH9 | c.153C>T p.S51= | Splice Region (SNP) | VAF 41/203 reads (20%) | catalogued as rs746302834; called by muse, mutect2, varscan2
- MYCT1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as COSV65891401; called by muse, mutect2, varscan2
- MYH4 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV55118090; called by muse, mutect2, varscan2
- NOS1 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57613128; called by muse, mutect2, varscan2
- NUP205 | c.4964C>T p.T1655I | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as rs1027548377; called by muse, mutect2, varscan2
- OLAH | c.274G>A p.D92N (on ENST00000378228 / NM_001039702.3; = p.D145N on NM_018324.3) | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs774664197, COSV65491981; called by muse, mutect2, varscan2
- OR52I2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 84/477 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100443007; called by muse, mutect2, varscan2
- OR6M1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146786799, COSV58433701; called by muse, mutect2
- OR7D2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100712982; called by muse, mutect2, varscan2
- PKHD1 | c.10728G>A p.W3576* | Nonsense Mutation (SNP) | VAF 57/427 reads (13%) | catalogued as CM034285; called by muse, mutect2, varscan2
- PPM1F | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs374278330; called by muse, varscan2
- PREX2 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1213028913, COSV55766250; called by muse, mutect2, varscan2
- PTPRC | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 96/483 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs746480752; called by muse, mutect2, varscan2
- RBMXL3 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.098); catalogued as rs1327052767, COSV57756900; called by muse, mutect2, varscan2
- RELN | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.955); catalogued as rs762404220, COSV100633134; called by muse, mutect2, varscan2
- RGPD4 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766011043, COSV61745628; called by mutect2, varscan2
- RPL26L1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1482092927; called by muse, mutect2, varscan2
- SEMA4F | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 85/420 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs367999393, COSV60282393; called by muse, mutect2, varscan2
- SIPA1L3 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 77/391 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs757004604, COSV55924065; called by muse, mutect2, varscan2
- SLC30A8 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201697165; called by muse, mutect2, varscan2
- SLC41A2 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51611051; called by muse, mutect2, varscan2
- SLC5A5 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs952808056, COSV55834862; called by muse, mutect2, varscan2
- SLCO4C1 | c.1469+1G>A p.X490_splice | Splice Site (SNP) | VAF 30/195 reads (15%) | catalogued as COSV60516776; called by muse, mutect2, varscan2
- SLIT2 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV56565528, COSV56587278; called by muse, mutect2, varscan2
- SLITRK1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100999945; called by muse, mutect2, varscan2
- TMPRSS3 | c.803G>A p.W268* | Nonsense Mutation (SNP) | VAF 55/270 reads (20%) | catalogued as COSV52303072, COSV99368788; called by muse, mutect2, varscan2
- TMPRSS6 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs755334877; called by muse, mutect2, varscan2
- TRBV6-1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 59/357 reads (17%) | catalogued as rs763678098; called by muse, varscan2
- TSGA10 | c.1928G>A p.R643K | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV61823712; called by muse, mutect2
- UGT2A3 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52362595; called by muse, mutect2, varscan2
- VRK3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1001069402; called by muse, mutect2, varscan2
- WDR59 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 93/401 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs752321244, COSV50936520; called by muse, mutect2, varscan2
- ZFHX4 | c.9269A>C p.H3090P | Missense Mutation (SNP) | VAF 74/503 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV50637074; called by muse, mutect2, varscan2
- ZIC4 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1342760692, COSV67173763; called by muse, mutect2, varscan2
- ZNF366 | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as rs750970053; called by muse, mutect2, varscan2
- ZNF716 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs782304244, COSV70779917, COSV70782546; called by muse, mutect2, varscan2
- A4GNT | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3667G>A p.A1223T | Missense Mutation (SNP) | VAF 76/430 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY2 | c.3199G>A p.G1067R | Missense Mutation (SNP) | VAF 86/445 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKEF1 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 187/562 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ANKS1A | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- AOX1 | c.3997C>T p.P1333S | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ARHGAP30 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ATF7IP2 | c.960G>A p.Q320= | Splice Region (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- ATP1B3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATR | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- C6orf89 | c.418T>C p.W140R (on ENST00000373685; = p.W147R on NM_152734.4) | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CCDC168 | c.19306G>A p.A6436T | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CCT8L2 | c.95A>C p.H32P | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CDKN1C | c.778_788del p.N260Dfs*22 | Frame Shift Del (DEL) | VAF 44/294 reads (15%) | called by mutect2, pindel, varscan2
- CFAP298-TCP10L | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CPLX2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 73/489 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DNAH7 | c.7573G>A p.E2525K | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EPS15L1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ERVV-1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ERVV-1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM153CP | n.391T>G | Splice Region (SNP) | VAF 57/336 reads (17%) | called by mutect2, varscan2
- FAM83H | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 75/574 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FOXL1 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GP1BA | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- HHIP | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HIVEP2 | c.2577T>G p.S859R | Missense Mutation (SNP) | VAF 94/364 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ITGB1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- KCNA7 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 76/407 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KCNK13 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRIQ1 | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGI2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM | c.2805G>A p.K935= | Splice Region (SNP) | VAF 44/230 reads (19%) | called by muse, mutect2, varscan2
- MIA3 | c.5429C>T p.P1810L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLLT1 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MS4A1 | c.440dup p.L147Ffs*10 | Frame Shift Ins (INS) | VAF 39/254 reads (15%) | called by mutect2, pindel, varscan2
- MUC12 | c.14593G>A p.E4865K (on ENST00000379442; = p.E4722K on NM_001164462.1) | Missense Mutation (SNP) | VAF 108/511 reads (21%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2
- MUC16 | c.5449G>A p.D1817N | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- NAV2 | c.6115C>T p.L2039F (on ENST00000396087 / NM_001244963.2; = p.L1980F on NM_145117.5) | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NDST3 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- NRP2 | c.2095T>C p.Y699H | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPRD1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 105/497 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PADI3 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAX2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- PCDHA11 | c.2285G>A p.G762D | Missense Mutation (SNP) | VAF 91/503 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PDE6A | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHA6 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 104/442 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POF1B | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRKAR1B | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 66/401 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRSS55 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PSD | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTGFRN | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SETD2 | c.6508_6512del p.G2170Sfs*12 | Frame Shift Del (DEL) | VAF 75/417 reads (18%) | called by mutect2, pindel, varscan2
- SHISA6 | c.1274C>T p.S425L (on ENST00000409168 / NM_001173461.1; = p.S476L on NM_207386.4) | Missense Mutation (SNP) | VAF 103/458 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SIPA1L3 | c.703T>G p.C235G | Missense Mutation (SNP) | VAF 85/495 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9C1 | c.2798A>T p.K933M | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SOX30 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TACR3 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 55/420 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX22 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TECTA | c.59A>T p.H20L | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- THSD7B | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TLE4 | c.1130T>G p.V377G | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAJ7 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 40/329 reads (12%) | called by muse, mutect2, varscan2
- VPS33B | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZBTB7C | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZC3H12B | c.1892G>A p.G631D | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ZNF250 | c.164A>T p.Y55F | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF606 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAM29 | c.1809G>A p.E603= | Silent (SNP) | VAF 76/434 reads (18%) | catalogued as rs764914357; called by muse, mutect2, varscan2
- ADAMTS5 | c.2250G>A p.R750= | Silent (SNP) | VAF 66/376 reads (18%) | catalogued as COSV53184704; called by muse, mutect2, varscan2
- APCDD1 | c.1086C>T p.F362= | Silent (SNP) | VAF 43/289 reads (15%) | catalogued as rs768170068, COSV62372441; called by muse, mutect2, varscan2
- ATP13A4 | c.348C>T p.I116= | Silent (SNP) | VAF 51/318 reads (16%) | catalogued as rs1323825756; called by muse, mutect2, varscan2
- C6 | c.1728C>T p.T576= | Silent (SNP) | VAF 41/283 reads (14%) | called by muse, mutect2, varscan2
- CASR | c.1944C>T p.F648= (on ENST00000490131; = p.F725= on NM_000388.4) | Silent (SNP) | VAF 67/407 reads (16%) | catalogued as rs1474434486, COSV56134256; called by muse, mutect2, varscan2
- CELSR1 | c.264G>T p.L88= | Silent (SNP) | VAF 122/514 reads (24%) | catalogued as COSV104392780; called by muse, mutect2, varscan2
- CHRNA9 | c.1392C>T p.F464= | Silent (SNP) | VAF 48/325 reads (15%) | catalogued as COSV59575127; called by muse, mutect2, varscan2
- CLVS2 | c.603C>T p.V201= | Silent (SNP) | VAF 60/252 reads (24%) | called by muse, mutect2, varscan2
- CYP4F2 | c.906C>T p.L302= | Silent (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- DNAH2 | c.6138G>A p.E2046= | Silent (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- DNAH9 | c.2706C>T p.S902= | Silent (SNP) | VAF 44/294 reads (15%) | catalogued as rs778407556; called by muse, mutect2, varscan2
- DOCK3 | c.2031C>T p.I677= | Silent (SNP) | VAF 69/337 reads (20%) | called by muse, mutect2, varscan2
- FOS | c.1038C>T p.P346= | Silent (SNP) | VAF 83/373 reads (22%) | catalogued as rs200095017; called by muse, mutect2, varscan2
- G6PD | c.45C>T p.I15= | Silent (SNP) | VAF 77/224 reads (34%) | catalogued as rs1557233203; called by muse, mutect2, varscan2
- GABRQ | c.1032G>A p.L344= | Silent (SNP) | VAF 109/284 reads (38%) | called by muse, mutect2, varscan2
- GNA11 | c.210G>A p.E70= | Silent (SNP) | VAF 86/465 reads (18%) | catalogued as rs1257006905; called by muse, mutect2, varscan2
- GPR22 | c.1119A>G p.K373= | Silent (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
- KCNH5 | c.1671G>A p.G557= | Silent (SNP) | VAF 91/432 reads (21%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.366C>T p.I122= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99383446; called by muse, mutect2
- KMT2D | c.15975C>T p.P5325= | Silent (SNP) | VAF 50/353 reads (14%) | catalogued as rs780850935, COSV56416697; called by muse, mutect2, varscan2
- KRT14 | c.1152G>A p.L384= | Silent (SNP) | VAF 75/422 reads (18%) | called by muse, mutect2, varscan2
- LEP | c.403C>T p.L135= | Silent (SNP) | VAF 70/441 reads (16%) | called by muse, mutect2, varscan2
- LHX9 | c.744G>A p.E248= | Silent (SNP) | VAF 44/263 reads (17%) | called by muse, mutect2, varscan2
- MAN2B2 | c.987C>T p.F329= | Silent (SNP) | VAF 61/359 reads (17%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2382T>C p.V794= | Silent (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- MRTFA | c.459C>T p.S153= | Silent (SNP) | VAF 51/275 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.23142C>T p.P7714= | Silent (SNP) | VAF 81/406 reads (20%) | catalogued as COSV67451049; called by muse, mutect2, varscan2
- NAB1 | c.1365C>T p.S455= | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as rs1444348233; called by muse, mutect2, varscan2
- NCAN | c.3965G>A p.*1322= | Silent (SNP) | VAF 62/269 reads (23%) | called by muse, mutect2, varscan2
- NIBAN1 | c.2346G>A p.G782= | Silent (SNP) | VAF 118/606 reads (19%) | called by muse, mutect2, varscan2
- NLRP4 | c.954G>A p.P318= | Silent (SNP) | VAF 55/327 reads (17%) | catalogued as rs371991895, COSV56719096; called by muse, mutect2, varscan2
- OBSCN | c.2289C>T p.L763= | Silent (SNP) | VAF 87/485 reads (18%) | catalogued as rs1374442050; called by muse, mutect2, varscan2
- OR1D5 | c.630C>T p.P210= | Silent (SNP) | VAF 47/297 reads (16%) | catalogued as rs776119243; called by muse, mutect2, varscan2
- OR2T4 | c.435C>T p.F145= | Silent (SNP) | VAF 127/643 reads (20%) | catalogued as rs1313221663, COSV63543478, COSV63543719; called by muse, mutect2, varscan2
- OR5D13 | c.474C>T p.S158= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as COSV62333247, COSV62335408; called by muse, mutect2, varscan2
- OTOP2 | c.1527C>T p.I509= | Silent (SNP) | VAF 53/295 reads (18%) | catalogued as COSV58883381; called by muse, mutect2, varscan2
- PCDHB5 | c.1842C>T p.F614= | Silent (SNP) | VAF 118/714 reads (17%) | called by muse, mutect2, varscan2
- PCDHB9 | c.2322C>T p.L774= | Silent (SNP) | VAF 73/435 reads (17%) | catalogued as rs565662126, COSV53383336; called by muse, mutect2, varscan2
- PDE3A | c.417C>T p.L139= | Silent (SNP) | VAF 96/546 reads (18%) | catalogued as COSV62976344; called by muse, mutect2, varscan2
- PDE3A | c.418C>T p.L140= | Silent (SNP) | VAF 94/546 reads (17%) | catalogued as rs775502767; called by muse, mutect2, varscan2
- PENK | c.597G>A p.L199= | Silent (SNP) | VAF 81/498 reads (16%) | catalogued as rs1177714975; called by muse, mutect2, varscan2
- PHKG2 | c.618C>T p.T206= | Silent (SNP) | VAF 90/406 reads (22%) | catalogued as rs773624428; called by muse, mutect2, varscan2
- PIEZO2 | c.6318C>T p.S2106= | Silent (SNP) | VAF 64/360 reads (18%) | called by muse, mutect2, varscan2
- PIP5K1C | c.756C>T p.F252= | Silent (SNP) | VAF 86/448 reads (19%) | catalogued as rs1326102430, COSV58953908; called by muse, varscan2
- PKD1 | c.4773C>T p.I1591= | Silent (SNP) | VAF 77/454 reads (17%) | catalogued as rs373958724, COSV99237257; called by muse, mutect2, varscan2
- PLD2 | c.1674C>T p.H558= | Silent (SNP) | VAF 82/423 reads (19%) | catalogued as rs1567531965, COSV99562087; called by muse, mutect2, varscan2
- PRKAR1B | c.240G>A p.E80= | Silent (SNP) | VAF 69/403 reads (17%) | called by muse, mutect2, varscan2
- PRKAR2B | c.1023C>T p.I341= | Silent (SNP) | VAF 64/377 reads (17%) | catalogued as rs567791710, COSV99708166; called by muse, mutect2, varscan2
- PRSS1 | c.382C>T p.L128= | Silent (SNP) | VAF 145/623 reads (23%) | called by muse, mutect2, varscan2
- PTPRD | c.3027C>T p.V1009= | Silent (SNP) | VAF 52/282 reads (18%) | called by muse, mutect2, varscan2
- PTPRT | c.2184C>T p.S728= | Silent (SNP) | VAF 52/346 reads (15%) | called by muse, mutect2, varscan2
- RAI1 | c.4884C>T p.S1628= | Silent (SNP) | VAF 83/532 reads (16%) | catalogued as rs763401743; called by muse, mutect2, varscan2
- RBBP5 | c.531C>T p.V177= | Silent (SNP) | VAF 44/235 reads (19%) | called by muse, mutect2, varscan2
- RMDN2 | c.1038C>T p.F346= (on ENST00000354545 / NM_001322212.2; = p.F524= on NM_144713.5) | Silent (SNP) | VAF 23/183 reads (13%) | called by muse, mutect2, varscan2
- SFXN1 | c.765C>T p.A255= | Silent (SNP) | VAF 21/388 reads (5%) | called by muse, mutect2
- SHOX2 | c.375G>A p.E125= (on ENST00000441443 / NM_006884.3; = p.E149= on NM_003030.4) | Silent (SNP) | VAF 27/256 reads (11%) | catalogued as rs1140219; called by muse, mutect2, varscan2
- SLC12A3 | c.2754C>T p.F918= (on ENST00000563236 / NM_001126108.2; = p.F927= on NM_000339.3) | Silent (SNP) | VAF 52/313 reads (17%) | called by muse, mutect2, varscan2
- SOWAHB | c.1218G>A p.E406= | Silent (SNP) | VAF 76/478 reads (16%) | called by muse, mutect2, varscan2
- SPTBN4 | c.630G>A p.R210= | Silent (SNP) | VAF 60/293 reads (20%) | called by muse, mutect2, varscan2
- TANC2 | c.4542C>T p.Y1514= | Silent (SNP) | VAF 101/466 reads (22%) | called by muse, mutect2, varscan2
- TMCC2 | c.1950C>T p.I650= | Silent (SNP) | VAF 87/456 reads (19%) | catalogued as rs371544078, COSV100319229; called by muse, mutect2, varscan2
- TNNI3 | c.264G>A p.L88= | Silent (SNP) | VAF 70/347 reads (20%) | catalogued as rs772928416; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTC21A | c.357C>T p.F119= | Silent (SNP) | VAF 68/392 reads (17%) | called by muse, mutect2, varscan2
- TTC28 | c.5886G>A p.Q1962= | Silent (SNP) | VAF 69/430 reads (16%) | called by muse, mutect2, varscan2
- TTC7A | c.933C>T p.F311= | Silent (SNP) | VAF 66/429 reads (15%) | catalogued as COSV55408115; called by muse, mutect2, varscan2
- UGT1A3 | c.414C>T p.I138= | Silent (SNP) | VAF 66/360 reads (18%) | catalogued as COSV59398235; called by muse, mutect2, varscan2
- USP29 | c.42C>T p.S14= | Silent (SNP) | VAF 27/238 reads (11%) | called by muse, mutect2, varscan2
- VARS1 | c.3783G>A p.Q1261= | Silent (SNP) | VAF 74/449 reads (16%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.954G>A p.K318= (on ENST00000268616; = p.K455= on NM_015144.3) | Silent (SNP) | VAF 35/266 reads (13%) | called by muse, mutect2, varscan2
- ATXN8OS | n.499+804C>T | Intron (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- CCNJ | c.-171G>A | 5'UTR (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- CHCHD5 | c.309+53C>T | Intron (SNP) | VAF 77/445 reads (17%) | catalogued as COSV61424635; called by muse, mutect2, varscan2
- EPHA6 | c.1606+29A>C | Intron (SNP) | VAF 48/371 reads (13%) | called by muse, mutect2, varscan2
- GRAMD1A | chr19:34996112 G>A | 5'Flank (SNP) | VAF 72/466 reads (15%) | called by muse, mutect2, varscan2
- NCAM1 | c.*1975A>T | 3'UTR (SNP) | VAF 64/374 reads (17%) | called by muse, mutect2, varscan2
- NKG7 | c.304+22G>A | Intron (SNP) | VAF 97/534 reads (18%) | catalogued as rs561618955; called by muse, mutect2, varscan2
- PLCH2 | c.2959+266C>T | Intron (SNP) | VAF 117/577 reads (20%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+310C>T | Intron (SNP) | VAF 97/487 reads (20%) | called by muse, mutect2, varscan2
